Somatic mutation profile of tumor specimen TARGET-20-PASREH-09A (aliquot TARGET-20-PASREH-09A-02D) from TARGET case TARGET-20-PASREH, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.1 years (2,608 days).
Specimen TARGET-20-PASREH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1373223e-ff7e-48a6-bc1a-d6673f6fda43.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASREH-14A (Bone Marrow Normal), aliquot TARGET-20-PASREH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e65b922b-de2e-4741-b0ed-12bb55cbb7ca

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NCOR1 | c.6424_6427dup p.S2143Cfs*19 | Frame Shift Ins (INS) | VAF 43/147 reads (29%) | called by mutect2, pindel, varscan2
- NCOR1 | c.4316_4317insG p.A1440Sfs*21 | Frame Shift Ins (INS) | VAF 63/214 reads (29%) | called by mutect2, pindel, varscan2
- NF1 | c.1042_1043insTTGCCAGT p.S348Ffs*31 | Frame Shift Ins (INS) | VAF 58/142 reads (41%) | called by mutect2, pindel, varscan2
